Somatic mutation profile of tumor specimen TCGA-QR-A6H0-01A (aliquot TCGA-QR-A6H0-01A-11D-A35D-08) from TCGA case TCGA-QR-A6H0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Paraganglioma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 53.0 years (19,372 days).
Specimen TCGA-QR-A6H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 882809fd-58a3-41ad-93dc-89fec555c667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6H0-10A (Blood Derived Normal), aliquot TCGA-QR-A6H0-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b39162a8-09eb-4982-9536-adbc6baf004e

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TULP1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs944741344, COSV57692284; called by muse, mutect2, varscan2
- ARMC3 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LCA5 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SLC25A44 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NLGN1 | c.336A>G p.Q112= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs1162264368; called by muse, mutect2, varscan2
